Somatic mutation profile of tumor specimen TARGET-10-PATXSK-09A (aliquot TARGET-10-PATXSK-09A-01D) from TARGET case TARGET-10-PATXSK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,279 days).
Specimen TARGET-10-PATXSK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b07b168e-5d78-470a-88e4-deb3de21ecba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATXSK-10A (Blood Derived Normal), aliquot TARGET-10-PATXSK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3616d87-49e1-48d9-abe2-e20954d86116

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 4, Silent 2, Nonsense Mutation 2, 3'Flank 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS5 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53177822; called by muse, mutect2, varscan2
- CDH11 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745457288, COSV51775913; called by muse, mutect2, varscan2
- CELSR1 | c.3200G>A p.R1067Q | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as rs752742697, COSV53098965; called by muse, mutect2, varscan2
- DNM2 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV58971002; called by muse, mutect2, varscan2
- JAK1 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61086725; called by muse, mutect2, varscan2
- JAK1 | c.1954T>C p.Y652H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as COSV61088550, COSV61093090, COSV61093632; called by muse, mutect2
- JAK3 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752661478, COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2, varscan2
- LRP3 | c.2152C>T p.R718W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs745884839, COSV53506986; called by muse, mutect2, varscan2
- MYBPHL | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs766582821, COSV64062976; called by muse, mutect2, varscan2
- NOTCH1 | c.5039T>A p.I1680N | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53025693, COSV53032125, COSV53096766; called by muse, mutect2, varscan2
- PCDH11Y | c.1646G>A p.R549H (on ENST00000400457 / NM_032973.2; = p.R538H on NM_032971.3) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs1381302441, COSV53089767; called by muse, mutect2, varscan2
- PHIP | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51510130; called by muse, mutect2, varscan2
- SLC30A5 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV66500985; called by muse, mutect2, varscan2
- ST6GAL2 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 21/61 reads (34%) | PolyPhen probably damaging (0.918); catalogued as rs1416447332, COSV64527671, COSV64528971; called by muse, mutect2, varscan2
- VGLL4 | c.236G>C p.R79P | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757511716, COSV56076030, COSV56081386; called by muse, mutect2, varscan2
- ZFAT | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV64742435; called by muse, mutect2, varscan2
- ZP2 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs143028903; called by muse, mutect2, varscan2
- MYO6 | c.3646A>G p.M1216V (on ENST00000369981; = p.M1206V on NM_004999.4) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- LAMC3 | c.2940C>T p.N980= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs940847303, COSV63088518; called by muse, mutect2, varscan2
- LRRTM4 | c.330A>G p.R110= | Silent (SNP) | VAF 48/86 reads (56%) | called by muse, mutect2, varscan2
- C11orf86 | c.-32G>A | 5'UTR (SNP) | VAF 15/23 reads (65%) | catalogued as rs948960313; called by muse, mutect2, varscan2
- CDIPT | chr16:29865220 C>A | 5'Flank (SNP) | VAF 14/27 reads (52%) | called by muse, varscan2
- EYS | c.8072-2884G>A | Intron (SNP) | VAF 8/25 reads (32%) | catalogued as rs750835713; called by muse, mutect2, varscan2
- LAG3 | c.1431+104T>C | Intron (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- RSPO3 | c.97+53G>A | Intron (SNP) | VAF 12/22 reads (55%) | catalogued as rs935106414; called by muse, mutect2, varscan2
- SEPTIN7P9 | chr10:38383180 del AAC | 3'Flank (DEL) | VAF 28/82 reads (34%) | catalogued as rs1424263129; called by pindel, varscan2
- SLC5A12 | c.525+114A>C | Intron (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
